Somatic mutation profile of tumor specimen TCGA-A3-3319-01A (aliquot TCGA-A3-3319-01A-01D-0966-08) from TCGA case TCGA-A3-3319, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.4 years (25,699 days).
Specimen TCGA-A3-3319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c96aac14-93c4-486e-95fe-f7d139a52f23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3319-11A (Solid Tissue Normal), aliquot TCGA-A3-3319-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bf215bb-95e8-4f54-857c-adedc0239419

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Frame Shift Del 4, Intron 3, Nonsense Mutation 3, 3'Flank 2, Frame Shift Ins 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALLC | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as rs755429246, COSV52994164, COSV99378331; called by muse, mutect2, varscan2
- ATP7B | c.3181G>A p.G1061R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349853812; called by muse, mutect2, varscan2
- B3GLCT | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as rs1399744680; called by muse, mutect2, varscan2
- BRINP2 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196713538, COSV64180002; called by muse, mutect2, varscan2
- ELMO1 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV60305261; called by muse, mutect2, varscan2
- LRRC42 | c.898A>G p.N300D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.115); catalogued as rs1226349388; called by muse, mutect2, varscan2
- MFSD13A | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53266623; called by muse, mutect2, varscan2
- NDST2 | c.1922A>G p.E641G | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104401641; called by muse, mutect2, varscan2
- PREX1 | c.3016G>C p.D1006H | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs757101993; called by muse, mutect2, varscan2
- SLC5A11 | c.26A>G p.Q9R | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs758887512; called by muse, mutect2, varscan2
- SZT2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.52); catalogued as COSV60290698; called by muse, mutect2, varscan2
- TARS2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs756811374; called by muse, mutect2, varscan2
- ZNF175 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs941405880; called by muse, mutect2, varscan2
- AC092143.1 | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ACO1 | c.1898T>A p.L633Q | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- C1S | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC24 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 93/354 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DDX46 | c.1576G>T p.V526F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2
- DIO2 | c.781A>T p.N261Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.883); called by muse, varscan2
- DNAJB4 | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ERC1 | c.2315A>G p.K772R (on ENST00000360905 / NM_178040.4; = p.K744R on NM_178039.4) | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAT3 | c.3655G>C p.E1219Q | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GARRE1 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPRC5C | c.1367A>G p.E456G (on ENST00000652232; = p.E411G on NM_018653.4) | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HS1BP3 | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGLON5 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- KLF12 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KLHL4 | c.1756del p.S586Qfs*37 | Frame Shift Del (DEL) | VAF 41/76 reads (54%) | called by mutect2, pindel, varscan2
- KLK6 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- LRRTM1 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MEI1 | c.2677C>A p.L893M | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MEX3B | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MICAL3 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 94/297 reads (32%) | called by muse, mutect2, varscan2
- MOCS3 | c.1037A>T p.D346V | Missense Mutation (SNP) | VAF 291/656 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- MYO15A | c.9104C>T p.S3035F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- NFASC | c.1382C>T p.T461I (on ENST00000339876 / NM_001378329.1; = p.T472I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PCCB | c.1303T>C p.Y435H | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH7 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAG1 | c.1958G>C p.S653T | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RAD54L2 | c.938T>A p.L313* | Nonsense Mutation (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- RESF1 | c.3890T>G p.L1297W | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- RIOK2 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 126/526 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, varscan2
- SGCA | c.25_26insAA p.P9Qfs*39 | Frame Shift Ins (INS) | VAF 83/376 reads (22%) | called by mutect2, pindel, varscan2
- SLC15A4 | c.1383dup p.G462Wfs*65 | Frame Shift Ins (INS) | VAF 42/138 reads (30%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.3691G>A p.A1231T | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SMC1B | c.3456T>G p.D1152E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SPAG1 | c.2447_2448del p.L816Qfs*6 | Frame Shift Del (DEL) | VAF 47/155 reads (30%) | called by pindel, varscan2
- SYNRG | c.3723del p.N1241Kfs*12 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | called by mutect2, pindel, varscan2
- TBL1XR1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMEM182 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRDMT1 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TTC3 | c.205_211del p.I69Vfs*17 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel, varscan2
- UBE4B | c.3580_3582del p.G1194del (on ENST00000343090 / NM_001105562.3; = p.G1065del on NM_006048.5) | In Frame Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- UNC13B | c.2713A>T p.M905L | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP15 | c.898A>C p.M300L (on ENST00000280377 / NM_001351159.2; = p.M271L on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YARS1 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ADGRV1 | c.13386G>A p.G4462= | Silent (SNP) | VAF 79/138 reads (57%) | called by muse, mutect2, varscan2
- ANK2 | c.2349T>C p.H783= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1432284899; called by muse, mutect2, varscan2
- ASH1L | c.2445C>G p.V815= | Silent (SNP) | VAF 70/280 reads (25%) | catalogued as rs1393051424; called by muse, mutect2, varscan2
- CC2D2A | c.2541C>T p.D847= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs1212761897; called by muse, mutect2, varscan2
- CDH11 | c.120G>A p.E40= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CHD1 | c.2100A>G p.K700= | Silent (SNP) | VAF 128/263 reads (49%) | called by muse, mutect2, varscan2
- CNNM4 | c.2274T>G p.L758= | Silent (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- LRP5 | c.3549C>G p.T1183= | Silent (SNP) | VAF 40/186 reads (22%) | called by muse, mutect2, varscan2
- MEX3A | c.663C>T p.P221= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs765160121; called by mutect2, varscan2
- MTFR1 | c.642A>G p.R214= | Silent (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- SEC31A | c.1053A>G p.S351= | Silent (SNP) | VAF 46/192 reads (24%) | catalogued as rs1221266124; called by muse, mutect2, varscan2
- SERPINH1 | c.765C>T p.I255= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs369937589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1B3 | c.1650A>G p.T550= | Silent (SNP) | VAF 123/352 reads (35%) | catalogued as rs763443499, COSV53936718; called by muse, mutect2, varscan2
- SPECC1 | c.90C>T p.S30= | Silent (SNP) | VAF 55/260 reads (21%) | catalogued as rs199639674, COSV54959759; called by muse, mutect2, varscan2
- ACSM1 | c.1197+186C>T | Intron (SNP) | VAF 144/343 reads (42%) | catalogued as rs764236242; called by muse, varscan2
- AP4B1 | c.*1_*2del | 3'UTR (DEL) | VAF 19/72 reads (26%) | catalogued as rs1302681844; called by mutect2, pindel, varscan2
- CNOT11 | chr2:101272947 A>G | 3'Flank (SNP) | VAF 37/173 reads (21%) | called by muse, mutect2, varscan2
- NSRP1 | c.20+250A>G | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-1798C>T | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- USP34 | chr2:61186466 C>G | 3'Flank (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
